Somatic mutation profile of tumor specimen C3N-03767-01 (aliquot CPT0247970006) from CPTAC case C3N-03767, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 66.1 years (24,142 days).
Specimen C3N-03767-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13be174c-a219-487c-8a89-c836920def61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03767-31 (Blood Derived Normal), aliquot CPT0247990002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1983376f-a11b-4987-a034-da838d04194d

The open-access MAF lists 86 somatic variants for this specimen: 53 protein-altering or splice-affecting, 25 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 25, Nonsense Mutation 7, Intron 3, 3'UTR 3, Frame Shift Del 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NR3C2 | c.1935C>A p.C645* | Nonsense Mutation (SNP) | VAF 50/383 reads (13%) | catalogued as rs121912564, CM031296; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTN1 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51990767; called by muse, mutect2, varscan2
- ANO2 | c.37C>T p.R13C (on ENST00000356134 / NM_001278597.3; = p.R17C on NM_001278596.3) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as rs766546668, COSV59041835; called by mutect2, varscan2
- B4GALNT1 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 25/295 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.523); catalogued as rs777129843, COSV100247338; called by muse, mutect2
- CSAG3 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 168/770 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1408019978; called by muse, mutect2, varscan2
- DDX21 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 76/377 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100826509; called by muse, mutect2, varscan2
- ENDOG | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 276/498 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs769611074; called by muse, mutect2, varscan2
- EXOC4 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs577020229; called by muse, mutect2, varscan2
- FAM189A1 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 78/287 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs886480344; called by muse, mutect2, varscan2
- GNAS | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 161/777 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.847); catalogued as COSV55687853; called by muse, mutect2, varscan2
- HMCN1 | c.6196C>T p.R2066* | Nonsense Mutation (SNP) | VAF 77/269 reads (29%) | catalogued as COSV54919730; called by muse, mutect2, varscan2
- KIAA0753 | c.2060G>A p.R687H | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.104); catalogued as rs758932943; called by muse, mutect2, varscan2
- MUC17 | c.5396C>A p.P1799Q | Missense Mutation (SNP) | VAF 24/303 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV60295591; called by muse, mutect2
- NCAN | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 381/522 reads (73%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs771653162, COSV53052005; called by muse, mutect2, varscan2
- NEK8 | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs140363905; called by muse, mutect2, varscan2
- NPTX1 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 269/445 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as rs148347894; called by muse, mutect2, varscan2
- OR13A1 | c.599C>A p.P200H | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65573142; called by muse, mutect2, varscan2
- RGS9 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 48/744 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs756410417, COSV99288104; called by muse, mutect2
- SERPING1 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 83/437 reads (19%) | catalogued as CD053612; called by muse, mutect2, varscan2
- TENM1 | c.261C>A p.Y87* | Nonsense Mutation (SNP) | VAF 19/178 reads (11%) | catalogued as COSV64430349; called by muse, mutect2, varscan2
- UBL4B | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 87/143 reads (61%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as rs375641562, COSV61944832; called by muse, mutect2, varscan2
- XIRP2 | c.7495G>A p.E2499K (on ENST00000628543; = p.E2674K on NM_152381.6) | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.278); catalogued as rs768719822, COSV54690550; called by muse, mutect2, varscan2
- ZNF587B | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 63/272 reads (23%) | catalogued as rs756443862; called by muse, mutect2, varscan2
- AAGAB | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 42/317 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP10A | c.1536G>C p.K512N | Missense Mutation (SNP) | VAF 97/374 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- BCORL1 | c.1373G>T p.G458V | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- BTBD19 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 74/576 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- C17orf50 | c.332G>T p.R111M | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CCDC91 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 5/135 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- CFAP58 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- CHPF2 | c.2150T>G p.F717C | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FHDC1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.029); called by muse, mutect2
- FNIP1 | c.2165T>A p.M722K | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPR50 | c.502A>C p.T168P | Missense Mutation (SNP) | VAF 66/288 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- HTR2B | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM3A | c.3617C>G p.P1206R | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMNTD2 | c.1793A>T p.D598V | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MAGEL2 | c.1319C>A p.A440D | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MEX3C | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 70/129 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MUC4 | c.1160T>C p.F387S | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- MYCN | c.1174del p.Q392Sfs*21 | Frame Shift Del (DEL) | VAF 146/746 reads (20%) | called by mutect2, pindel, varscan2
- MYH4 | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRG1 | c.175A>C p.I59L (on ENST00000523534; = p.I206L on NM_013962.2) | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- OR11H2 | c.842T>G p.F281C (on ENST00000556246; = p.F292C on NM_001197287.1) | Missense Mutation (SNP) | VAF 154/474 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- OR6C75 | c.357C>A p.D119E | Missense Mutation (SNP) | VAF 71/323 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCLO | c.12761A>C p.K4254T | Missense Mutation (SNP) | VAF 89/302 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNB1 | c.6343A>T p.M2115L | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- SEZ6 | c.2480C>T p.A827V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- TMED4 | c.464_475delinsG p.E155Gfs*7 | Frame Shift Del (DEL) | VAF 31/234 reads (13%) | called by pindel, varscan2*
- TMEM260 | c.1684C>G p.L562V | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- TNS3 | c.33C>A p.Y11* | Nonsense Mutation (SNP) | VAF 91/292 reads (31%) | called by muse, mutect2, varscan2
- TPRG1L | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- XKR6 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 106/298 reads (36%) | called by muse, mutect2, varscan2
- A2ML1 | c.2241G>A p.S747= | Silent (SNP) | VAF 47/264 reads (18%) | catalogued as rs770762334, COSV55301114; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC191 | c.2562C>T p.I854= | Silent (SNP) | VAF 33/332 reads (10%) | catalogued as rs776236811; called by muse, mutect2, varscan2
- CNR1 | c.879G>A p.A293= | Silent (SNP) | VAF 118/216 reads (55%) | catalogued as rs35057475; called by muse, mutect2, varscan2
- CNRIP1 | c.291G>A p.T97= | Silent (SNP) | VAF 152/662 reads (23%) | catalogued as rs369650513, COSV55148810; called by muse, mutect2, varscan2
- EDA2R | c.660C>T p.D220= | Silent (SNP) | VAF 73/381 reads (19%) | catalogued as rs749216567, COSV53633218; ClinVar: likely benign; called by muse, mutect2, varscan2
- IL22RA2 | c.75G>A p.T25= | Silent (SNP) | VAF 19/124 reads (15%) | catalogued as rs374860051; called by muse, mutect2, varscan2
- IRAK1 | c.718A>C p.R240= | Silent (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- MAGEE2 | c.219C>T p.D73= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs749734220, COSV64898399; called by mutect2, varscan2
- MRO | c.330T>C p.S110= | Silent (SNP) | VAF 105/206 reads (51%) | called by muse, mutect2, varscan2
- MUC17 | c.11319C>A p.T3773= | Silent (SNP) | VAF 73/204 reads (36%) | called by muse, mutect2, varscan2
- NLRP13 | c.12T>C p.S4= | Silent (SNP) | VAF 21/226 reads (9%) | called by muse, mutect2
- PDZD2 | c.5073G>A p.S1691= | Silent (SNP) | VAF 22/307 reads (7%) | catalogued as rs200988906, COSV99227141; called by muse, mutect2
- PDZD3 | c.669G>T p.L223= (on ENST00000531114; = p.L157= on NM_024791.4) | Silent (SNP) | VAF 39/194 reads (20%) | catalogued as COSV52702874; called by muse, mutect2, varscan2
- PLEC | c.2346C>T p.S782= (on ENST00000322810 / NM_201380.4; = p.S672= on NM_000445.5) | Silent (SNP) | VAF 100/679 reads (15%) | catalogued as rs916055245; called by muse, mutect2, varscan2
- POM121L12 | c.735C>T p.L245= | Silent (SNP) | VAF 35/271 reads (13%) | catalogued as COSV101374895, COSV68693088; called by muse, mutect2, varscan2
- PSMD1 | c.729G>A p.L243= | Silent (SNP) | VAF 35/271 reads (13%) | catalogued as rs1430420315; called by muse, mutect2
- RRP36 | c.153G>A p.E51= | Silent (SNP) | VAF 24/198 reads (12%) | called by muse, mutect2, varscan2
- SCN2A | c.2232A>C p.P744= | Silent (SNP) | VAF 77/183 reads (42%) | called by muse, mutect2, varscan2
- SI | c.105A>T p.T35= | Silent (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- SLC39A5 | c.876C>T p.L292= | Silent (SNP) | VAF 36/381 reads (9%) | catalogued as rs1169278030; called by muse, mutect2
- SOX21 | c.663G>A p.G221= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs961883121; called by muse, mutect2, varscan2
- TACC2 | c.300G>A p.P100= | Silent (SNP) | VAF 101/269 reads (38%) | catalogued as rs373182521; called by muse, mutect2, varscan2
- TDRD6 | c.66C>T p.D22= | Silent (SNP) | VAF 57/300 reads (19%) | catalogued as rs758235858, COSV60174421; called by muse, mutect2, varscan2
- TYK2 | c.3021C>T p.I1007= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- VWF | c.7335G>A p.E2445= | Silent (SNP) | VAF 72/809 reads (9%) | catalogued as rs1487209314, COSV54627164; called by muse, mutect2
- CFAP157 | c.*1456G>T | 3'UTR (SNP) | VAF 149/246 reads (61%) | called by muse, mutect2, varscan2
- EDRF1 | c.-15C>G | 5'UTR (SNP) | VAF 52/101 reads (51%) | called by muse, mutect2
- EYS | c.8072-2980T>C | Intron (SNP) | VAF 6/27 reads (22%) | catalogued as rs1049463364; called by muse, varscan2
- H3-2 | c.*287G>A | 3'UTR (SNP) | VAF 149/287 reads (52%) | catalogued as rs782774027; called by muse, mutect2, varscan2
- PPP1R8 | c.117+1640G>A | Intron (SNP) | VAF 41/161 reads (25%) | called by muse, mutect2, varscan2
- TLK1 | c.331-5744T>C | Intron (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2
- TPO | c.*11G>T | 3'UTR (SNP) | VAF 28/326 reads (9%) | called by muse, mutect2
- ZNF502 | c.-9G>A | 5'UTR (SNP) | VAF 35/312 reads (11%) | catalogued as rs777955950; called by muse, mutect2
